Somatic mutation profile of tumor specimen TCGA-24-0982-01A (aliquot TCGA-24-0982-01A-01W-0486-08) from TCGA case TCGA-24-0982, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.2 years (28,201 days).
Specimen TCGA-24-0982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff0a7ce-24eb-4eb0-88bf-bd8af4e1cd60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-0982-10C (Blood Derived Normal), aliquot TCGA-24-0982-10C-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aee419ad-54f7-4cb7-97fc-be807a6846ed

The open-access MAF lists 71 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 416/652 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BLVRA | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 30/504 reads (6%) | catalogued as rs754440828, COSV55516258; called by muse, mutect2
- CBLN4 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 125/170 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756451061, COSV50352834; called by muse, mutect2, varscan2
- CDH22 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 184/1218 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs755330428, COSV64839607; called by muse, varscan2
- CELSR2 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54776701, COSV99604570; called by muse, varscan2
- CLDN15 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759019587, COSV57659722; called by muse, mutect2, varscan2
- CNOT1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100409875; called by muse, mutect2
- COG8 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs966313565, COSV99650877; called by muse, mutect2, varscan2
- DLGAP5 | c.1141T>G p.C381G | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV55965236; called by muse, mutect2, varscan2
- DOCK1 | c.3601G>A p.V1201I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs952439430, COSV54744547; called by muse, mutect2, varscan2
- FAM83A | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs376602872; called by muse, mutect2, varscan2
- FBN2 | c.3021G>T p.W1007C | Missense Mutation (SNP) | VAF 239/1694 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV52544043; called by muse, mutect2, varscan2
- FGB | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 200/517 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM141545, COSV57419491; called by muse, mutect2, varscan2
- FLG | c.5548G>A p.E1850K | Missense Mutation (SNP) | VAF 107/1450 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.262); catalogued as rs1377089283, COSV64237232; called by muse, mutect2
- GLCE | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55948308; called by muse, mutect2, varscan2
- HYAL3 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs189065354, COSV100269767; called by muse, mutect2, varscan2
- IARS1 | c.2385C>G p.D795E | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65117059; called by muse, mutect2, varscan2
- IBTK | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs376172634; called by muse, mutect2
- L3MBTL2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV99345722; called by muse, mutect2
- PADI2 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 358/577 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV64946639; called by muse, mutect2, varscan2
- PCDHB5 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.068); catalogued as rs1554275802, COSV99169358; called by muse, mutect2, varscan2
- PDE11A | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV53707732; called by muse, varscan2
- PPP2R2B | c.1184T>G p.V395G (on ENST00000394409; = p.V461G on NM_181674.2) | Missense Mutation (SNP) | VAF 245/1774 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778098894, COSV60751353; called by muse, varscan2
- PREPL | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV53219280; called by muse, mutect2
- PSMB5 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV57801268; called by muse, mutect2, varscan2
- RGS21 | c.84C>A p.N28K | Missense Mutation (SNP) | VAF 104/550 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1461487573, COSV69883934; called by muse, mutect2, varscan2
- SCAMP5 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 127/346 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.506); catalogued as COSV62644176; called by muse, mutect2, varscan2
- SGPL1 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 36/654 reads (6%) | catalogued as rs1196497635; called by muse, mutect2
- SIDT1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 73/551 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV53506725; called by muse, mutect2, varscan2
- SLC17A6 | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1308349633, COSV54141104; called by muse, mutect2, varscan2
- SLC35C2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 192/680 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV54758409; called by muse, mutect2, varscan2
- SMC1A | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV59131791; called by muse, mutect2, varscan2
- STXBP5L | c.1562A>G p.Y521C | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as COSV56533814; called by muse, mutect2, varscan2
- SYBU | c.1979G>A p.R660H (on ENST00000276646 / NM_001099754.2; = p.R659H on NM_017786.6) | Missense Mutation (SNP) | VAF 94/594 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs74885615; called by muse, mutect2, varscan2
- TAB1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53372445; called by muse, mutect2
- TBC1D10A | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1033312863, COSV99304901; called by muse, mutect2, varscan2
- TOR1B | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs868804067, COSV99399963; called by muse, mutect2
- TP53I11 | c.528T>G p.I176M | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57534163; called by muse, mutect2, varscan2
- TUB | c.1364T>A p.F455Y (on ENST00000299506 / NM_177972.3; = p.F510Y on NM_003320.4) | Missense Mutation (SNP) | VAF 404/1327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109960; called by muse, mutect2, varscan2
- ZKSCAN2 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60158645; called by muse, mutect2, varscan2
- ZNF16 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 184/933 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV52765486; called by muse, mutect2, varscan2
- ZNF276 | c.334G>A p.V112M (on ENST00000443381 / NM_001113525.2; = p.V37M on NM_152287.4) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs979535399, COSV99234485, COSV99235269; called by muse, mutect2, varscan2
- ZNF653 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs765890535, COSV99542096; called by muse, mutect2
- ALMS1 | c.3740T>G p.I1247S | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2
- ITGB4 | c.953del p.N318Tfs*58 | Frame Shift Del (DEL) | VAF 109/197 reads (55%) | called by mutect2, pindel, varscan2
- NLRP5 | c.3022T>C p.S1008P | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2
- OR5V1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 38/772 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- PAPLN | c.3280G>C p.D1094H (on ENST00000554301; = p.D1067H on NM_173462.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- POSTN | c.2466dup p.V823Sfs*5 | Frame Shift Ins (INS) | VAF 38/89 reads (43%) | called by mutect2, pindel, varscan2
- SLC6A6 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2
- TMTC4 | c.1519G>T p.E507* (on ENST00000376234 / NM_001350577.2; = p.E526* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- TOP2A | c.620_624dup p.F209Sfs*32 | Frame Shift Ins (INS) | VAF 561/1514 reads (37%) | called by pindel, varscan2
- ZSCAN10 | c.914C>T p.S305F (on ENST00000252463; = p.S360F on NM_032805.3) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- ADAMTS12 | c.2349G>C p.L783= | Silent (SNP) | VAF 289/1879 reads (15%) | catalogued as COSV61278572; called by muse, mutect2, varscan2
- CCDC40 | c.2517C>T p.D839= | Silent (SNP) | VAF 92/162 reads (57%) | catalogued as COSV66478609; called by muse, mutect2, varscan2
- COL16A1 | c.654C>G p.V218= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as COSV54713439; called by muse, mutect2, varscan2
- DGCR8 | c.252C>T p.R84= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100708130; called by muse, mutect2, varscan2
- DNAJB6 | c.570G>A p.S190= | Silent (SNP) | VAF 38/393 reads (10%) | catalogued as COSV51094840, COSV51100787; called by muse, mutect2
- DNM1 | c.1773G>A p.T591= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as rs762812488, COSV57849538; called by muse, mutect2, varscan2
- KCNA5 | c.558G>A p.R186= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs778119687, COSV52907929; called by muse, mutect2, varscan2
- LRIG2 | c.2319G>A p.G773= | Silent (SNP) | VAF 37/345 reads (11%) | catalogued as COSV63164148; called by muse, mutect2, varscan2
- MBL2 | c.144C>A p.G48= | Silent (SNP) | VAF 108/444 reads (24%) | catalogued as COSV64758688; called by muse, mutect2, varscan2
- MYO16 | c.153G>A p.A51= | Silent (SNP) | VAF 51/220 reads (23%) | catalogued as rs749546658, COSV51805323; called by muse, mutect2, varscan2
- MYOM2 | c.3150T>C p.I1050= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV50768437; called by muse, mutect2, varscan2
- NCAPD2 | c.3177G>A p.L1059= | Silent (SNP) | VAF 34/1457 reads (2%) | called by muse, mutect2
- NPLOC4 | c.735G>A p.G245= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- OTUD4 | c.2805C>T p.G935= (on ENST00000447906 / NM_001366057.1; = p.G870= on NM_001102653.1) | Silent (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- RGS9 | c.1614G>A p.Q538= | Silent (SNP) | VAF 36/334 reads (11%) | catalogued as rs75082589, COSV99287884; called by muse, mutect2
- SERPINB5 | c.1071C>A p.I357= | Silent (SNP) | VAF 18/714 reads (3%) | called by muse, mutect2
- SPAG16 | c.819T>C p.G273= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV55989629; called by muse, mutect2, varscan2
- WNT4 | c.313+2325C>T | Intron (SNP) | VAF 8/14 reads (57%) | catalogued as rs761137242, COSV51605443; called by muse, mutect2, varscan2
